Somatic mutation profile of tumor specimen HTMCP-03-06-02365-01A (aliquot HTMCP-03-06-02365-01A-01D-9392) from CGCI case HTMCP-03-06-02365, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 43.6 years (15,942 days).
Specimen HTMCP-03-06-02365-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2090b193-5246-4fdb-a13b-c19d8b756453.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02365-10A (Blood Derived Normal), aliquot HTMCP-03-06-02365-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d336fb8b-9866-4a32-b7e1-e04fb28bd243

The open-access MAF lists 48 somatic variants for this specimen: 37 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 9, Nonsense Mutation 4, 5'Flank 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 47/168 reads (28%) | hotspot (GDC flag); catalogued as COSV65037942; called by muse, mutect2, varscan2
- ADCY8 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.278); catalogued as rs867019467; called by muse, mutect2, varscan2
- CCDC88A | c.5437G>A p.E1813K (on ENST00000436346 / NM_001365480.1; = p.E1785K on NM_018084.5) | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.647); catalogued as rs749349350, COSV99710696; called by muse, mutect2, varscan2
- CNTNAP5 | c.2515C>G p.R839G | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV70474923; called by muse, mutect2, varscan2
- COL11A1 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100618102; called by muse, mutect2, varscan2
- F8 | c.4789G>A p.E1597K | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as CM111354, COSV100811860; called by muse, mutect2, varscan2
- FREM2 | c.2092C>T p.R698C | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.663); catalogued as rs755029984, COSV54829802; called by muse, mutect2, varscan2
- GRM5 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.49); catalogued as COSV100555021, COSV59605587; called by muse, mutect2, varscan2
- KCNA1 | c.471C>G p.F157L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as COSV66836976; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MMP19 | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs372055008, COSV59450945; called by muse, mutect2, varscan2
- OR4C13 | c.457C>A p.H153N | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV73648671; called by muse, mutect2, varscan2
- PPP6R3 | c.1543C>G p.L515V (on ENST00000393800 / NM_001352375.2; = p.L464V on NM_018312.5) | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs747348539; called by muse, mutect2, varscan2
- THSD7B | c.2063G>A p.W688* | Nonsense Mutation (SNP) | VAF 10/189 reads (5%) | catalogued as COSV99745458; called by muse, mutect2
- ZAN | c.2970del p.T991Pfs*10 | Frame Shift Del (DEL) | VAF 22/204 reads (11%) | catalogued as COSV61812039; called by mutect2, varscan2
- ZNF257 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV71306210; called by muse, mutect2, varscan2
- ZNF687 | c.3097C>T p.R1033C | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745563703; called by muse, mutect2, varscan2
- ADAR | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 38/176 reads (22%) | called by muse, mutect2, varscan2
- AKAP12 | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- BLM | c.3521G>A p.G1174E | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BRWD1 | c.2878C>G p.Q960E | Missense Mutation (SNP) | VAF 94/192 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CACNB4 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CYLD | c.944G>A p.R315K | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DHX57 | c.1087C>T p.H363Y | Missense Mutation (SNP) | VAF 152/331 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- EIF2AK3 | c.2162C>G p.S721C | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- FASN | c.5250A>T p.E1750D | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); called by muse, mutect2
- GRIK1 | c.727-1G>A p.X243_splice | Splice Site (SNP) | VAF 27/194 reads (14%) | called by muse, mutect2, varscan2
- HS6ST2 | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KALRN | c.4348C>G p.P1450A | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRRK2 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- MYH10 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- NPY5R | c.33G>C p.K11N | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- PPP2R3A | c.3298G>C p.E1100Q | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PTPDC1 | c.715G>C p.E239Q (on ENST00000375360 / NM_177995.3; = p.E291Q on NM_152422.4) | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- PTPRF | c.585G>C p.E195D | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SLIT3 | c.2674G>A p.D892N | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- SRGAP3 | c.1702C>T p.Q568* | Nonsense Mutation (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- ERICH6B | c.696C>T p.D232= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs997466438; called by muse, mutect2, varscan2
- FCGBP | c.6852G>A p.P2284= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs1157282541; called by muse, mutect2, varscan2
- OR4S1 | c.93C>T p.L31= | Silent (SNP) | VAF 12/213 reads (6%) | catalogued as COSV100180165; called by muse, mutect2
- OTOA | c.2100G>A p.G700= (on ENST00000286149; = p.G686= on NM_144672.4) | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV99623876; called by muse, mutect2, varscan2
- PCLO | c.11358G>A p.E3786= | Silent (SNP) | VAF 105/258 reads (41%) | catalogued as rs1438840466; called by muse, mutect2, varscan2
- ST18 | c.2319C>T p.C773= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as rs369209561; called by muse, mutect2, varscan2
- TARBP1 | c.3072G>A p.K1024= | Silent (SNP) | VAF 15/256 reads (6%) | catalogued as rs1020793191; called by muse, mutect2
- WDR87 | c.1989C>T p.F663= | Silent (SNP) | VAF 11/296 reads (4%) | called by muse, mutect2
- ZNF658 | c.222G>A p.L74= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs771433662; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915706 C>T | 5'Flank (SNP) | VAF 14/87 reads (16%) | called by muse, mutect2, varscan2
- PTGER4P2 | chr9:62837861 G>A | 5'Flank (SNP) | VAF 6/39 reads (15%) | called by mutect2, varscan2
